Somatic mutation profile of tumor specimen 0DTGDD from CCDI case PBCJWE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 15.3 years (5,591 days).
Specimen 0DTGDD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eabbc555-8a04-462e-ac4a-bad0c4aa6883.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTGDI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01cdf67e-114d-47fc-bfc4-ec27a5aa9f31

The open-access MAF lists 27 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 5, Nonsense Mutation 3, Frame Shift Del 3, 5'UTR 1, Frame Shift Ins 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 249/576 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.40C>T p.R14* | Nonsense Mutation (SNP) | VAF 173/456 reads (38%) | hotspot (GDC flag); catalogued as rs1362274408, COSV55920408; called by muse, mutect2, varscan2
- C4BPA | c.194C>T p.T65M | Missense Mutation (SNP) | VAF 278/598 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs767519496, COSV65536828; called by muse, varscan2
- COLQ | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 45/712 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as rs531584926, COSV104432196; ClinVar: uncertain significance; called by muse, mutect2
- GTF3C4 | c.1037A>G p.N346S | Missense Mutation (SNP) | VAF 23/768 reads (3%) | SIFT tolerated (0.47); PolyPhen benign (0.041); catalogued as rs1378021066; called by muse, mutect2
- HPRT1 | c.430C>G p.Q144E | Missense Mutation (SNP) | VAF 47/409 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as CM082890; called by muse, mutect2, varscan2
- MXRA5 | c.7289C>T p.T2430M | Missense Mutation (SNP) | VAF 200/463 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.073); catalogued as rs376795964, COSV54235079; called by muse, mutect2, varscan2
- OR5H6 | c.752G>A p.R251Q (on ENST00000642105; = p.R235Q on NM_001005479.2) | Missense Mutation (SNP) | VAF 205/651 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.248); catalogued as rs145676438; called by muse, mutect2, varscan2
- PIGT | c.883G>T p.E295* | Nonsense Mutation (SNP) | VAF 255/544 reads (47%) | catalogued as COSV54126081; called by muse, mutect2, varscan2
- RNF227 | c.375C>G p.S125R | Missense Mutation (SNP) | VAF 169/332 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.079); catalogued as rs1226688334; called by muse, mutect2, varscan2
- SHANK3 | c.3593G>A p.R1198Q | Missense Mutation (SNP) | VAF 216/509 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as rs1408829143; called by muse, mutect2, varscan2
- ZBTB7C | c.1288G>A p.V430M | Missense Mutation (SNP) | VAF 244/520 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs941256667; called by muse, mutect2, varscan2
- ADGRG2 | c.1850G>A p.R617K (on ENST00000379869 / NM_001079858.3; = p.R614K on NM_005756.4) | Missense Mutation (SNP) | VAF 194/404 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- CCDC154 | c.1026_1039del p.V343Gfs*144 | Frame Shift Del (DEL) | VAF 199/559 reads (36%) | called by mutect2, pindel, varscan2
- CRYBG3 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 275/887 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- KMT2D | c.10172_10196del p.M3391Sfs*34 | Frame Shift Del (DEL) | VAF 92/428 reads (21%) | called by mutect2, pindel, varscan2
- PTCH1 | c.2287dup p.V763Gfs*27 | Frame Shift Ins (INS) | VAF 769/1155 reads (67%) | called by mutect2, pindel, varscan2
- RSPH3 | c.70_71del p.G24Wfs*66 | Frame Shift Del (DEL) | VAF 342/917 reads (37%) | called by mutect2, pindel, varscan2
- UNC13D | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 220/508 reads (43%) | called by muse, mutect2, varscan2
- BABAM1 | c.642C>T p.I214= | Silent (SNP) | VAF 305/664 reads (46%) | catalogued as COSV63921434; called by muse, mutect2, varscan2
- BMP10 | c.351G>A p.P117= | Silent (SNP) | VAF 127/291 reads (44%) | catalogued as rs372335613, COSV54897300; called by muse, mutect2, varscan2
- MCF2L2 | c.687G>A p.L229= | Silent (SNP) | VAF 311/1115 reads (28%) | called by muse, mutect2, varscan2
- PHRF1 | c.684G>A p.P228= | Silent (SNP) | VAF 300/662 reads (45%) | catalogued as rs367849960; called by muse, mutect2, varscan2
- SYF2 | c.73C>T p.L25= | Silent (SNP) | VAF 82/766 reads (11%) | called by muse, mutect2, varscan2
- ATP11B | c.-1A>G | 5'UTR (SNP) | VAF 220/716 reads (31%) | called by muse, mutect2, varscan2
- MUC2 | chr11:1099205 C>T | 3'Flank (SNP) | VAF 16/134 reads (12%) | called by muse, varscan2
- SIPA1L3 | c.*19G>A | 3'UTR (SNP) | VAF 104/222 reads (47%) | catalogued as rs377002875; called by muse, mutect2, varscan2
